CCDI case PBCLBP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e0f85d84-319b-49f1-b2b3-7b78f1da406e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,602 days).

Biospecimens (3 samples)
- Sample 0DUUP2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUUPL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUUQ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
